Somatic mutation profile of tumor specimen CDDP-ACNN-TTP1-A (aliquot CDDP-ACNN-TTP1-A-2-0-D-A572-36) from CDDP_EAGLE case CDDP-ACNN, project CDDP_EAGLE-1: CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 67 years.
Specimen CDDP-ACNN-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8447fc8c-8cc2-4fa4-a60b-a382a29a7bc7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen CDDP-ACNN-NB1-A (Blood Derived Normal), aliquot CDDP-ACNN-NB1-A-1-0-D-A572-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/270d6f63-e289-4af1-9e6f-e876fb834c15

The open-access MAF lists 181 somatic variants for this specimen: 119 protein-altering or splice-affecting, 37 silent, 25 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 101, Silent 37, Intron 14, Nonsense Mutation 9, RNA 4, Frame Shift Del 3, 5'UTR 3, 5'Flank 2, Splice Region 2, Frame Shift Ins 2, 3'Flank 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 266/579 reads (46%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ACTBL2 | c.113G>A p.R38H | Missense Mutation (SNP) | VAF 22/270 reads (8%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.085); catalogued as rs765705222, COSV99067477; called by muse, mutect2
- ACTC1 | c.766C>T p.R256C | Missense Mutation (SNP) | VAF 73/222 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.946); catalogued as rs1179943060, COSV51757242, COSV51759304; called by muse, mutect2, varscan2
- ADAMTS17 | c.2830C>T p.R944W | Missense Mutation (SNP) | VAF 102/542 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs767325627, COSV51483098; called by muse, mutect2, varscan2
- AGBL2 | c.1727G>A p.R576H | Missense Mutation (SNP) | VAF 33/248 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.009); catalogued as rs754816884, COSV54091073; called by muse, mutect2, varscan2
- ANK2 | c.4222G>A p.E1408K | Missense Mutation (SNP) | VAF 60/368 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100002399, COSV52143804; called by muse, mutect2
- AP3B2 | c.2251C>T p.P751S | Missense Mutation (SNP) | VAF 26/200 reads (13%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV55612744; called by muse, mutect2, varscan2
- ATOH1 | c.973G>A p.E325K | Missense Mutation (SNP) | VAF 30/202 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.025); catalogued as COSV60038710; called by muse, mutect2, varscan2
- BFSP2 | c.275G>A p.G92D | Missense Mutation (SNP) | VAF 19/122 reads (16%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.602); catalogued as COSV56588902; called by muse, mutect2, varscan2
- CDH7 | c.125G>T p.R42M | Missense Mutation (SNP) | VAF 63/290 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.541); catalogued as COSV59888395; called by muse, mutect2, varscan2
- CDKN2AIP | c.1108C>G p.L370V | Missense Mutation (SNP) | VAF 24/228 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.123); catalogued as COSV56627165; called by muse, mutect2, varscan2
- CHIT1 | c.401G>A p.G134D | Missense Mutation (SNP) | VAF 56/330 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55146502, COSV55147142; called by muse, mutect2, varscan2
- CSMD2 | c.3485G>A p.R1162H | Missense Mutation (SNP) | VAF 47/238 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.382); catalogued as rs201989989; called by muse, mutect2, varscan2
- ENPEP | c.379G>T p.A127S | Missense Mutation (SNP) | VAF 54/311 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.031); catalogued as rs767349194, COSV54450380; called by muse, mutect2, varscan2
- ESF1 | c.1441A>G p.K481E | Missense Mutation (SNP) | VAF 57/390 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs1370526231; called by muse, mutect2, varscan2
- FAT2 | c.2468G>T p.G823V | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.575); catalogued as COSV55819134; called by muse, mutect2
- FBN1 | c.5548C>T p.R1850C | Missense Mutation (SNP) | VAF 130/517 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.828); catalogued as rs750720912, COSV57312210; called by muse, mutect2, varscan2
- H3-5 | c.26G>T p.R9L | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as COSV61188507; called by mutect2, varscan2
- ITPR1 | c.7538-3C>T | Splice Region (SNP) | VAF 40/395 reads (10%) | catalogued as rs748317274; called by muse, mutect2, varscan2
- KAT7 | c.1632C>G p.I544M | Missense Mutation (SNP) | VAF 57/267 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.967); catalogued as rs1048489952, COSV52012923; called by muse, mutect2, varscan2
- KCNQ3 | c.778G>T p.E260* | Nonsense Mutation (SNP) | VAF 48/409 reads (12%) | catalogued as COSV101196158; called by muse, mutect2, varscan2
- LILRB4 | c.743C>T p.S248L | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.993); catalogued as COSV54405497; called by muse, varscan2
- LTN1 | c.3964A>G p.I1322V | Missense Mutation (SNP) | VAF 39/181 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs1382835443; called by muse, mutect2
- MFSD2A | c.1331A>G p.Y444C (on ENST00000372809 / NM_001136493.3; = p.Y431C on NM_032793.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 59/383 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs753615407; called by muse, mutect2, varscan2
- MMUT | c.1677-1G>T p.X559_splice | Splice Site (SNP) | VAF 66/491 reads (13%) | catalogued as CS050814, CS060551, COSV51273175; called by muse, mutect2, varscan2
- NRXN1 | c.616G>A p.D206N | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as rs200781129, COSV68032996, COSV99065640; called by mutect2, varscan2
- OR5T2 | c.937G>A p.V313M | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.457); catalogued as COSV57589547; called by muse, mutect2
- PADI2 | c.1541T>C p.M514T | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.102); catalogued as rs776797825; called by muse, mutect2, varscan2
- PDE3B | c.3034C>T p.Q1012* | Nonsense Mutation (SNP) | VAF 94/563 reads (17%) | catalogued as rs1555008295; called by muse, mutect2, varscan2
- PZP | c.3949G>T p.E1317* | Nonsense Mutation (SNP) | VAF 130/308 reads (42%) | catalogued as COSV54369052; called by muse, mutect2, varscan2
- RYR3 | c.2933C>A p.P978H | Missense Mutation (SNP) | VAF 66/328 reads (20%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.552); catalogued as COSV101212215; called by muse, mutect2
- SCN3B | c.493C>A p.L165I | Missense Mutation (SNP) | VAF 96/427 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.415); catalogued as rs1412069210; called by muse, mutect2, varscan2
- SEMG2 | c.295C>A p.H99N | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.87); catalogued as rs202124576; called by muse, mutect2, varscan2
- SIPA1L3 | c.5279C>T p.S1760L | Missense Mutation (SNP) | VAF 30/134 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1187003870; called by muse, mutect2, varscan2
- SLC1A5 | c.1186G>A p.V396M | Missense Mutation (SNP) | VAF 27/132 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.958); catalogued as rs201829701; called by muse, mutect2, varscan2
- SLC7A1 | c.1541C>T p.T514I | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV66330293; called by muse, mutect2, varscan2
- SMAD1 | c.713G>T p.G238V | Missense Mutation (SNP) | VAF 43/313 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV57473282; called by muse, mutect2, varscan2
- SOHLH2 | c.647G>C p.R216T | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101157942; called by muse, mutect2
- SPPL2B | c.1475G>C p.R492P | Missense Mutation (SNP) | VAF 24/187 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101476094; called by muse, mutect2, varscan2
- SPTA1 | c.3227G>T p.R1076L | Missense Mutation (SNP) | VAF 46/266 reads (17%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.737); catalogued as COSV100934710; called by muse, mutect2, varscan2
- ST18 | c.95A>G p.Y32C | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.029); catalogued as rs781069562; called by muse, mutect2
- STK11 | c.388G>T p.E130* | Nonsense Mutation (SNP) | VAF 73/254 reads (29%) | catalogued as HM080026, COSV58826710; called by muse, mutect2, varscan2
- TEP1 | c.2087A>G p.N696S | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.187); catalogued as rs1050379871, COSV99403042; called by muse, mutect2
- TMEM40 | c.568G>T p.G190C | Missense Mutation (SNP) | VAF 42/234 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53148948; called by muse, mutect2, varscan2
- TRPC7 | c.1030C>T p.R344C | Missense Mutation (SNP) | VAF 80/422 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs769827279; called by muse, mutect2
- ZNF407 | c.6025G>A p.E2009K | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.57); PolyPhen benign (0.028); catalogued as rs777440656, COSV55269121; called by mutect2, varscan2
- ABCG4 | c.1709A>T p.Y570F | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.657); called by muse, mutect2, varscan2
- ACACA | c.4516G>C p.D1506H | Missense Mutation (SNP) | VAF 84/530 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ACTA1 | c.334C>A p.L112I | Missense Mutation (SNP) | VAF 41/267 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- AHNAK | c.8413G>A p.E2805K | Missense Mutation (SNP) | VAF 38/184 reads (21%) | SIFT tolerated (0.6); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- BHLHE40 | c.657C>A p.C219* | Nonsense Mutation (SNP) | VAF 42/306 reads (14%) | called by muse, mutect2, varscan2
- BTBD11 | c.1315C>A p.L439M | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- BTN3A2 | c.648G>C p.E216D | Missense Mutation (SNP) | VAF 46/283 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- C2CD3 | c.2320G>T p.V774L | Missense Mutation (SNP) | VAF 58/307 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- CCIN | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 44/219 reads (20%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- CDH23 | c.2310C>A p.D770E | Missense Mutation (SNP) | VAF 38/250 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CDH6 | c.470C>A p.P157Q | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CEP44 | c.986del p.P329Qfs*29 | Frame Shift Del (DEL) | VAF 77/459 reads (17%) | called by mutect2, pindel, varscan2
- CHD6 | c.3820G>T p.V1274L | Missense Mutation (SNP) | VAF 28/212 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.165); called by muse, mutect2
- COL11A1 | c.5010T>A p.S1670R | Missense Mutation (SNP) | VAF 78/618 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.142); called by muse, mutect2
- COL4A5 | c.4472A>G p.Y1491C | Missense Mutation (SNP) | VAF 76/219 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CPB2 | c.1208C>A p.P403H | Missense Mutation (SNP) | VAF 62/383 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CRACD | c.572G>C p.R191P | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2
- CYP27A1 | c.862G>A p.E288K | Missense Mutation (SNP) | VAF 60/404 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- DCAF12L1 | c.1274A>T p.E425V | Missense Mutation (SNP) | VAF 45/136 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- DCLK1 | c.2106C>A p.N702K (on ENST00000360631 / NM_001330072.2; = p.T727N on NM_004734.5) | Missense Mutation (SNP) | VAF 25/164 reads (15%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- DDX59 | c.1022C>T p.S341F | Missense Mutation (SNP) | VAF 50/323 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- DMRTA2 | c.812G>T p.G271V | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- DNAH9 | c.4707G>T p.K1569N | Missense Mutation (SNP) | VAF 30/165 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- DSP | c.5406G>T p.K1802N | Missense Mutation (SNP) | VAF 33/204 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- DUSP13 | c.115_118del p.D39Kfs*8 | Frame Shift Del (DEL) | VAF 20/106 reads (19%) | called by mutect2, pindel, varscan2
- ELL2 | c.1183A>G p.N395D | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.607); called by muse, mutect2
- ELOA2 | c.642A>T p.Q214H | Missense Mutation (SNP) | VAF 50/229 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- FAT3 | c.11626T>C p.Y3876H | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- FBXL4 | c.1469A>T p.K490M | Missense Mutation (SNP) | VAF 104/442 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.339); called by muse, mutect2, varscan2
- FUCA1 | c.631del p.T211Qfs*16 | Frame Shift Del (DEL) | VAF 88/630 reads (14%) | called by mutect2, pindel, varscan2
- GALC | c.1818G>T p.R606S | Missense Mutation (SNP) | VAF 21/168 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0.078); called by muse, mutect2
- GAPVD1 | c.2931G>T p.W977C (on ENST00000394104; = p.W1004C on NM_015635.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/234 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- GTSF1 | c.389_391del p.N130del | In Frame Del (DEL) | VAF 40/231 reads (17%) | called by pindel, varscan2
- IDUA | c.1627C>T p.R543C | Missense Mutation (SNP) | VAF 20/171 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- IL4R | c.445C>T p.P149S | Missense Mutation (SNP) | VAF 62/397 reads (16%) | SIFT tolerated (0.69); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IL5RA | c.122C>T p.T41I | Missense Mutation (SNP) | VAF 35/225 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KASH5 | c.336-3C>T | Splice Region (SNP) | VAF 24/159 reads (15%) | called by muse, mutect2, varscan2
- KCNB2 | c.2179C>A p.P727T | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.038); called by muse, mutect2
- KCNQ5 | c.810G>A p.W270* | Nonsense Mutation (SNP) | VAF 39/195 reads (20%) | called by muse, mutect2
- LYZL6 | c.251A>C p.N84T | Missense Mutation (SNP) | VAF 38/211 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- MRPS9 | c.1003G>T p.G335C | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NANOGNB | c.40C>A p.L14I | Missense Mutation (SNP) | VAF 64/174 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.636); called by muse, mutect2, varscan2
- NOS2 | c.1833G>T p.M611I | Missense Mutation (SNP) | VAF 33/273 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NR5A2 | c.613T>A p.S205T (on ENST00000367362 / NM_205860.3; = p.S159T on NM_003822.5) | Missense Mutation (SNP) | VAF 29/217 reads (13%) | SIFT tolerated (0.81); PolyPhen benign (0); called by muse, mutect2, varscan2
- ODF2L | c.1817T>G p.I606S (on ENST00000317336; = p.I590S on NM_020729.3) | Missense Mutation (SNP) | VAF 43/276 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.318); called by muse, mutect2
- OLFM4 | c.188G>T p.G63V | Missense Mutation (SNP) | VAF 21/129 reads (16%) | SIFT tolerated (0.53); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- OR1C1 | c.784C>A p.P262T | Missense Mutation (SNP) | VAF 26/156 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OR2W1 | c.699C>A p.S233R | Missense Mutation (SNP) | VAF 41/284 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- OR4X2 | c.53T>C p.V18A | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.156); called by muse, mutect2
- OTOG | c.2773dup p.S925Ffs*74 | Frame Shift Ins (INS) | VAF 11/68 reads (16%) | called by mutect2, pindel, varscan2
- PCDHB9 | c.677C>A p.S226Y | Missense Mutation (SNP) | VAF 40/262 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- PCDHGA1 | c.1098dup p.A367Cfs*7 | Frame Shift Ins (INS) | VAF 20/108 reads (19%) | called by mutect2, pindel, varscan2
- PCDHGB2 | c.1169C>G p.A390G | Missense Mutation (SNP) | VAF 40/234 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PEX5L | c.394T>A p.S132T | Missense Mutation (SNP) | VAF 25/144 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- PHACTR4 | c.1555G>T p.E519* (on ENST00000373839 / NM_001350159.2; = p.E529* on NM_023923.4) | Nonsense Mutation (SNP) | VAF 40/246 reads (16%) | called by muse, mutect2
- PIEZO2 | c.6784T>A p.F2262I | Missense Mutation (SNP) | VAF 51/265 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- PYROXD2 | c.133A>T p.N45Y | Missense Mutation (SNP) | VAF 39/195 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- RYR3 | c.2932C>A p.P978T | Missense Mutation (SNP) | VAF 68/325 reads (21%) | SIFT tolerated (0.54); PolyPhen benign (0.005); called by muse, mutect2
- SPTB | c.782C>A p.P261H | Missense Mutation (SNP) | VAF 83/510 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TBC1D12 | c.625G>T p.A209S | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- TBC1D9B | c.2537G>T p.R846L | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.204); called by muse, mutect2, varscan2
- TEX101 | c.22C>A p.H8N (on ENST00000598265 / NM_001130011.3; = p.H26N on NM_031451.4) | Missense Mutation (SNP) | VAF 24/230 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRIM64B | c.907G>T p.E303* | Nonsense Mutation (SNP) | VAF 5/32 reads (16%) | called by mutect2, varscan2
- TTC5 | c.257C>G p.P86R | Missense Mutation (SNP) | VAF 26/213 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- TTN | c.54794G>T p.G18265V (on ENST00000591111; = p.G10841V on NM_003319.4) | Missense Mutation (SNP) | VAF 65/338 reads (19%) | PolyPhen probably damaging (1); called by muse, mutect2
- UNC13A | c.58T>C p.F20L | Missense Mutation (SNP) | VAF 22/165 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- UNC13C | c.4815G>T p.E1605D | Missense Mutation (SNP) | VAF 28/215 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.992); called by muse, mutect2
- USH2A | c.2853C>A p.C951* | Nonsense Mutation (SNP) | VAF 61/284 reads (21%) | called by muse, mutect2, varscan2
- VPS13B | c.544G>C p.G182R | Missense Mutation (SNP) | VAF 99/524 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.28); called by muse, mutect2, varscan2
- ZBED6 | c.1422T>A p.N474K | Missense Mutation (SNP) | VAF 24/175 reads (14%) | SIFT tolerated (1); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- ZBTB7C | c.88G>T p.D30Y | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.746); called by muse, mutect2, varscan2
- ZNF229 | c.2152G>T p.G718W | Missense Mutation (SNP) | VAF 46/283 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZP4 | c.125C>A p.A42D | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- ABCA12 | c.5868C>T p.Y1956= (on ENST00000272895 / NM_173076.3; = p.Y1638= on NM_015657.3) | Silent (SNP) | VAF 116/628 reads (18%) | catalogued as rs372118363; called by muse, mutect2
- APLNR | c.459T>A p.L153= | Silent (SNP) | VAF 14/52 reads (27%) | called by muse, mutect2, varscan2
- ARHGAP23 | c.3330C>T p.G1110= | Silent (SNP) | VAF 15/101 reads (15%) | catalogued as rs745556318; called by muse, mutect2, varscan2
- ARRB1 | c.1083G>T p.P361= | Silent (SNP) | VAF 21/106 reads (20%) | catalogued as COSV63575782; called by muse, mutect2, varscan2
- BTBD18 | c.708T>C p.N236= | Silent (SNP) | VAF 20/105 reads (19%) | catalogued as rs1230214809; called by muse, varscan2
- CDKN1C | c.324C>A p.P108= | Silent (SNP) | VAF 15/68 reads (22%) | called by muse, mutect2, varscan2
- CLDN10 | c.486G>T p.L162= | Silent (SNP) | VAF 52/341 reads (15%) | catalogued as COSV54824845; called by muse, mutect2, varscan2
- CSMD2 | c.10014T>A p.I3338= | Silent (SNP) | VAF 63/317 reads (20%) | called by muse, mutect2, varscan2
- CYP11B1 | c.543G>C p.R181= | Silent (SNP) | VAF 34/245 reads (14%) | called by muse, mutect2, varscan2
- DCLK3 | c.831G>T p.L277= | Silent (SNP) | VAF 24/132 reads (18%) | called by muse, mutect2, varscan2
- EN2 | c.408G>A p.A136= | Silent (SNP) | VAF 6/19 reads (32%) | called by muse, mutect2, varscan2
- EPS8L1 | c.463C>T p.L155= (on ENST00000201647 / NM_133180.3; = p.L28= on NM_017729.3) | Silent (SNP) | VAF 16/118 reads (14%) | called by muse, mutect2, varscan2
- FREM2 | c.6111G>A p.L2037= | Silent (SNP) | VAF 66/310 reads (21%) | catalogued as COSV99751092; called by muse, mutect2, varscan2
- GDAP1L1 | c.618C>A p.P206= | Silent (SNP) | VAF 34/211 reads (16%) | catalogued as COSV61155871; called by muse, mutect2, varscan2
- KIAA1549L | c.2367G>C p.R789= (on ENST00000321505; = p.R1086= on NM_012194.3) | Silent (SNP) | VAF 25/161 reads (16%) | called by muse, mutect2, varscan2
- LGI4 | c.372C>T p.R124= | Silent (SNP) | VAF 25/208 reads (12%) | called by muse, mutect2, varscan2
- LRRC9 | c.4254C>A p.V1418= | Silent (SNP) | VAF 31/160 reads (19%) | called by muse, mutect2, varscan2
- MGAT3 | c.1068G>A p.P356= | Silent (SNP) | VAF 28/153 reads (18%) | catalogued as rs1419236411; called by muse, mutect2, varscan2
- OR1S1 | c.435T>C p.Y145= | Silent (SNP) | VAF 13/109 reads (12%) | called by muse, mutect2, varscan2
- PCDH12 | c.1695G>T p.V565= | Silent (SNP) | VAF 35/213 reads (16%) | called by muse, mutect2, varscan2
- PCDHB9 | c.678C>A p.S226= | Silent (SNP) | VAF 39/258 reads (15%) | called by muse, mutect2, varscan2
- PF4V1 | c.63G>A p.A21= | Silent (SNP) | VAF 40/226 reads (18%) | catalogued as rs996437610; called by muse, mutect2, varscan2
- PTPMT1 | c.411C>T p.S137= | Silent (SNP) | VAF 35/151 reads (23%) | called by muse, mutect2, varscan2
- PXDNL | c.492G>A p.G164= | Silent (SNP) | VAF 58/380 reads (15%) | called by muse, mutect2
- RASGRP2 | c.300C>A p.I100= | Silent (SNP) | VAF 48/363 reads (13%) | called by muse, mutect2, varscan2
- RTL1 | c.2673C>A p.I891= | Silent (SNP) | VAF 18/102 reads (18%) | called by muse, mutect2, varscan2
- SCAPER | c.87A>T p.I29= | Silent (SNP) | VAF 112/452 reads (25%) | called by muse, mutect2, varscan2
- SLC13A5 | c.48C>T p.I16= | Silent (SNP) | VAF 41/180 reads (23%) | catalogued as rs1162464041; called by muse, mutect2, varscan2
- SORCS1 | c.2739G>A p.L913= | Silent (SNP) | VAF 27/165 reads (16%) | catalogued as COSV53855461; called by muse, mutect2, varscan2
- TECRL | c.432C>A p.T144= | Silent (SNP) | VAF 44/218 reads (20%) | catalogued as COSV67086832, COSV67090948; called by muse, mutect2
- TENT5B | c.21A>C p.G7= | Silent (SNP) | VAF 12/76 reads (16%) | called by muse, mutect2, varscan2
- TEX13C | c.852G>A p.T284= | Silent (SNP) | VAF 18/59 reads (31%) | catalogued as COSV66616748; called by muse, mutect2, varscan2
- TLL1 | c.2121T>C p.N707= | Silent (SNP) | VAF 82/401 reads (20%) | catalogued as rs1453270181; called by muse, mutect2
- TRAV1-2 | c.237A>T p.S79= | Silent (SNP) | VAF 18/153 reads (12%) | called by muse, mutect2, varscan2
- UNC80 | c.2178C>A p.T726= | Silent (SNP) | VAF 45/245 reads (18%) | called by muse, mutect2, varscan2
- VSTM2A | c.111G>T p.T37= | Silent (SNP) | VAF 91/376 reads (24%) | called by muse, mutect2, varscan2
- ZC3H6 | c.444C>T p.F148= | Silent (SNP) | VAF 104/719 reads (14%) | catalogued as rs758806203; called by muse, mutect2, varscan2
- AC084082.1 | n.281G>A | RNA (SNP) | VAF 31/261 reads (12%) | called by muse, mutect2, varscan2
- ADAMTS13 | c.825-25G>T | Intron (SNP) | VAF 22/78 reads (28%) | called by muse, mutect2, varscan2
- C10orf143 | c.69+3694G>C | Intron (SNP) | VAF 29/188 reads (15%) | called by muse, mutect2, varscan2
- CERS5 | c.198-4507A>T | Intron (SNP) | VAF 8/60 reads (13%) | called by muse, mutect2
- DAPK3 | c.828+63G>T | Intron (SNP) | VAF 23/59 reads (39%) | called by muse, mutect2, varscan2
- EFCAB2 | c.781+3113C>T | Intron (SNP) | VAF 61/286 reads (21%) | called by muse, mutect2, varscan2
- FAM153CP | chr5:178055921 C>A | 3'Flank (SNP) | VAF 62/428 reads (14%) | called by muse, mutect2, varscan2
- LINC01619 | n.1516G>T | RNA (SNP) | VAF 48/234 reads (21%) | called by muse, mutect2, varscan2
- LINC02876 | n.504G>T | RNA (SNP) | VAF 45/238 reads (19%) | called by muse, mutect2
- LY6G6E | chr6:31712110 G>A | 3'Flank (SNP) | VAF 52/358 reads (15%) | called by muse, mutect2, varscan2
- MBD1 | c.*33-268G>A | Intron (SNP) | VAF 40/210 reads (19%) | called by muse, mutect2, varscan2
- PRKN | c.734+48G>C | Intron (SNP) | VAF 27/131 reads (21%) | called by muse, mutect2, varscan2
- RAB5C | c.-19C>T | 5'UTR (SNP) | VAF 6/73 reads (8%) | called by muse, mutect2
- RGS12 | c.1882-398A>G | Intron (SNP) | VAF 30/284 reads (11%) | catalogued as rs1387657297; called by muse, mutect2, varscan2
- RUNX1T1 | c.88+13357G>T | Intron (SNP) | VAF 40/249 reads (16%) | called by muse, mutect2, varscan2
- SLC25A14 | c.594+337G>T | Intron (SNP) | VAF 72/248 reads (29%) | called by muse, varscan2
- TNP1 | c.-12del | 5'UTR (DEL) | VAF 18/118 reads (15%) | called by mutect2, pindel, varscan2
- TPK1 | c.185+15079C>G | Intron (SNP) | VAF 28/168 reads (17%) | catalogued as COSV100765655; called by muse, mutect2, varscan2
- TXNRD3 | c.1621-561C>G | Intron (SNP) | VAF 12/60 reads (20%) | called by muse, mutect2
- URGCP | c.164-12C>G | Intron (SNP) | VAF 55/356 reads (15%) | catalogued as rs781341808; called by muse, varscan2
- WWOX | c.107+50C>T | Intron (SNP) | VAF 22/156 reads (14%) | called by muse, mutect2, varscan2
- Y_RNA | chr1:31507796 A>T | 5'Flank (SNP) | VAF 22/134 reads (16%) | called by muse, mutect2
- ZEB2 | chr2:144520328 G>T | 5'Flank (SNP) | VAF 13/66 reads (20%) | called by muse, mutect2
- ZNF252P | n.777G>T | RNA (SNP) | VAF 22/126 reads (17%) | called by muse, mutect2
- ZNF45 | c.-18C>T | 5'UTR (SNP) | VAF 46/212 reads (22%) | catalogued as rs1054557559, COSV99524205; called by muse, mutect2
